EXCEPTIONAL_RESPONDERS case ER-ABEA — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/701b56b0-802a-4321-b9a9-7871367f0b79

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1966; Vital status: Alive.

Diagnoses (1)
1. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin of lower limb and hip; Site of resection or biopsy: Skin of lower limb and hip; Age at diagnosis: 31.2 years (11,411 days); Year of diagnosis: 1997; AJCC pathologic stage: Stage I; Days to last follow up: 6,422 days (17.6 years); Days to best overall response: 4,588 days (12.6 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 4,295 days (11.8 years); Days to treatment end: 4,701 days (12.9 years).
   Treatment given: Therapeutic agents: Carboplatin; Days to treatment start: 4,295 days (11.8 years); Days to treatment end: 4,400 days (12.0 years).
   Treatment given: Therapeutic agents: Paclitaxel; Days to treatment start: 4,295 days (11.8 years); Days to treatment end: 4,519 days (12.4 years).

Follow-up (1 entry)
- Days to follow up: 6,422 days (17.6 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 6,422 days (17.6 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABEA-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ABEA-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 15; Percent tumor nuclei: 15; Percent normal cells: 82; Percent necrosis: 3; Percent stromal cells: 0; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
